Surgical pathology report (de-identified scan), TCGA case TCGA-2A-A8VO, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Memorial Sloan Kettering Cancer Center, specimen TCGA-2A-A8VO-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:

PSA 5.6, cT1c, Gleason 3+3=6 in R and L TZ plus R apex (medial core), eMRI (+) in anterior TZ bilaterally

Specimens Submitted:

- 1: Prostate and seminal vesicles, radical prostatectomy
- 2: Periprostatic fat, excision
- 3: Prostate, anterior rectal wall margin near apex, biopsy

DIAGNOSIS:

1. Prostate and seminal vesicles, radical prostatectomy:

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:3

Total Gleason score:6

A minor Gleason 4 component is present

Tumor Location:

Involves Right anterior

Involves Left posterior

Involves Left anterior

Dominant tumor mass located in: anterior, right and left, apex to base

Vascular Invasion:

Not Identified

Perineural Invasion:

Identified

Tumor Multicentricity:

Not identified

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Established extracapsular extension

The location of the extracapsular extension is right and midline anterior, mid

Seminal Vesicles:

Not involved

Bladder Neck:

Invades bladder neck

Surgical Margins:

Tumor present at bladder neck

Tumor present at anterior basal margin

ICD O-3

Adenocarcinoma, NOS 8140/3

Site: Prostate 161.9

3/2/14

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

Non-Neoplastic Prostate:

Exhibits nodular hyperplasia

Staging (AJCC 1997):

pT4 (invades adjacent structures, i.e. bladder neck)

2. **SP: Periprostatic fat, excision:**

Benign fibro-vascular tissue

3. **Prostate, anterior rectal wall margin near apex, biopsy:**

Benign adipose tissue and one benign lymph node (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh, labeled "Prostate and seminal vesicles".

It consists of a prostate and seminal vesicles. The total weight is 45.5 grams.

The prostate measures 3.5cm from apex to base, 4cm transversely, and 3.5cm from anterior to posterior.

The right and left seminal vesicles measure 6 x 1.3 and 4 x 1.5 cm, respectively. The external surface of the prostate is smooth.

The prostate is inked (right=green, left=blue) and fixed in formalin overnight.

The prostate is serially cut from apex to base at approximately 3-4 mm intervals. The prostate is entirely submitted.

Summary of Sections: RA-right apical margin, LA-left apical margin, BN-bladder neck margin

RSV-right seminal vesicle, LSV-left seminal vesicle, A-G -serial sections of prostate (apex to base)

2.) The specimen is received in formalin, labeled "periprostatic fat" and consists of tan-yellow adipose tissue measuring 2.5 x 1.5 x 1.0 cm. No gross lesions are identified. The specimen is entirely submitted. Summary of sections: U - undesignated

3.) The specimen is received in formalin, labeled "anterior rectal wall margin of prostate near apex" and consists of tan-red soft tissue measuring 0.7 x 0.4 x 0.2 cm. The specimen is entirely submitted. Summary of sections: U - undesignated

Summary of Sections:

Part 1: Prostate and seminal vesicles, radical prostatectomy

Blocks	Block Designation	PCs
1	A	1
1	B	1
1	BN	1
1	C	1
1	D	1
1	E	1
1	F	1
1	G	1
1	LA	1
1	LSV	1
1	RA	1
1	RSV	1

Part 2: Periprostatic fat, excision

Blocks	Block Designation	PCs
--------	-------------------	-----

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

1 U 1

Part 3: Prostate, anterior rectal wall margin near apex, biopsy

Blocks	Block Designation	PCs
1	U	1

Source: NCI Genomic Data Commons file 68f6ab4f-7fe2-48ff-b7e3-85ae8fe2156a (TCGA-2A-A8VO.B699D2D8-1EB6-4BFE-A468-D1FFA5F32D98.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).